CCDI case PBCDCA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/9b0716ae-b412-403b-9331-203f6b99f0be

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Synovial sarcoma, biphasic: ICD-O-3 morphology code: 9043/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 11.5 years (4,190 days).

Biospecimens (3 samples)
- Sample 0DP4P3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP4PH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP4QD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
